TCGA case TCGA-CN-4734 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of mouth; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b80fdc9a-341d-4277-9664-8e8f770d9ddd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C06.0; Tissue or organ of origin: Cheek mucosa; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 70.5 years (25,753 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,690 days (4.6 years).
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 36; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 73 days; Days to treatment end: 115 days; Treatment dose: 5,400 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 115 days; Treatment outcome: No Measurable Disease.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 227 days; Disease response: Tumor Free.
- Days to follow up: 758 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,690 days (4.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A: Negative.
- EGFR amplification: Amplified.
- Involved Tissue, NOS human papillomavirus (ISH): Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2008.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CN-4734-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.4; Shortest dimension: 0.2.
  Slide TCGA-CN-4734-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-CN-4734-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-CN-4734-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CN-4734-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Anatomic organ subdivision: Buccal Mucosa; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 4; Alcohol history documented: Yes.
- Follow-up form 1: New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Surgery; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,690 days; disease-specific survival: no event (censored), 1,690 days; disease-free interval: no event (censored), 1,690 days; progression-free interval: no event (censored), 1,690 days.
